Somatic mutation profile of tumor specimen 0DDA7J from CCDI case PBBNHH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.4 years (4,168 days).
Specimen 0DDA7J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9256dd78-5a46-4160-a2ac-e8c2025c76d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDA70 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2f126bf-3529-4723-95db-81672040a04e

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 87/639 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- IPO7 | c.2254C>T p.R752C | Missense Mutation (SNP) | VAF 64/405 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs370431374, COSV65685005; called by muse, mutect2, varscan2
- ARID1A | c.4180A>G p.S1394G | Missense Mutation (SNP) | VAF 34/316 reads (11%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- BOLL | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 38/680 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.1); called by muse, mutect2
- CCNF | c.1758dup p.T587Yfs*30 | Frame Shift Ins (INS) | VAF 46/293 reads (16%) | called by mutect2, pindel, varscan2
- CYP1A2 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 43/278 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RAMP3 | c.310T>A p.C104S | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO1A | c.1527G>A p.A509= | Silent (SNP) | VAF 83/555 reads (15%) | catalogued as rs939181200; called by muse, mutect2, varscan2
- PIKFYVE | c.717T>G p.S239= | Silent (SNP) | VAF 105/618 reads (17%) | called by muse, mutect2, varscan2
- VAV1 | c.813C>T p.I271= | Silent (SNP) | VAF 52/322 reads (16%) | catalogued as rs753340238; called by muse, mutect2, varscan2
- SYCE1L | c.582-97C>T | Intron (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
